Somatic mutation profile of tumor specimen 0DX0R4 from CCDI case PBCPZA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 20.7 years (7,561 days).
Specimen 0DX0R4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9464273c-4d01-439b-b8a9-a48cb7b17903.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX0Q8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ccba980-c4c7-483f-8257-42571a599303

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.983G>A p.G328E | Missense Mutation (SNP) | VAF 356/748 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs387906589, CM091421, COSV55115990, COSV55115998; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- LRCH4 | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 156/576 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as rs530626700; called by muse, varscan2
- MGAT4D | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 182/416 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs770418801; called by muse, varscan2
- NFATC4 | c.1687G>A p.G563R | Missense Mutation (SNP) | VAF 264/575 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372741212; called by muse, varscan2
- RGL3 | c.1552C>T p.R518W | Missense Mutation (SNP) | VAF 64/630 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs189304178; called by muse, varscan2
- PRTN3 | c.33G>A p.A11= | Silent (SNP) | VAF 141/330 reads (43%) | catalogued as rs777853515, COSV52256604; called by muse, varscan2
